Somatic mutation profile of tumor specimen TCGA-DK-A1A7-01A (aliquot TCGA-DK-A1A7-01A-11D-A13W-08) from TCGA case TCGA-DK-A1A7, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 67.1 years (24,499 days).
Specimen TCGA-DK-A1A7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4b5b1e4-64e6-42ef-83e7-9440f51bec42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A1A7-10A (Blood Derived Normal), aliquot TCGA-DK-A1A7-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e3d3f77-3814-48c3-b7cd-7c34531a450d

The open-access MAF lists 246 somatic variants for this specimen: 194 protein-altering or splice-affecting, 45 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 45, Nonsense Mutation 14, Frame Shift Del 9, Splice Site 7, Intron 4, In Frame Del 3, Splice Region 2, Frame Shift Ins 1, RNA 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC2 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 14/20 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55538701; called by muse, mutect2, varscan2
- KDM6A | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 18/28 reads (64%) | hotspot (GDC flag); catalogued as COSV65037942; called by muse, varscan2
- MPL | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as rs750046020, CM090043, COSV65246319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TBX5 | c.426del p.A143Pfs*7 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs1565941003, COSV59859763; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC9 | c.2557G>C p.E853Q | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV53981828, COSV53981949; called by muse, mutect2
- ABI1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61019248; called by muse, mutect2, varscan2
- ACTG1 | c.570G>A p.M190I | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.043); catalogued as COSV59509969; called by muse, mutect2, varscan2
- ADAMTS12 | c.3788C>T p.T1263M | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs757177041, COSV100710420, COSV61263698; called by muse, mutect2, varscan2
- ADCY2 | c.2909T>C p.I970T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57891634; called by muse, mutect2, varscan2
- AL121899.2 | c.1823A>T p.D608V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV67351980; called by muse, mutect2, varscan2
- ANKRD28 | c.798T>A p.N266K | Missense Mutation (SNP) | VAF 95/315 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV67519642; called by muse, mutect2, varscan2
- ANPEP | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55593816; called by muse, mutect2, varscan2
- ARHGAP29 | c.2078C>A p.S693* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as COSV53118222; called by muse, mutect2, varscan2
- ARVCF | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as rs778549957, COSV52889561; called by muse, mutect2, varscan2
- B3GALT5 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as rs146778477, COSV58200069; called by muse, mutect2
- B4GALT7 | c.569T>G p.L190R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV50354725; called by muse, varscan2
- BBOF1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV58223538; called by muse, mutect2, varscan2
- BIRC6 | c.4499G>A p.S1500N | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV70203989; called by muse, mutect2, varscan2
- C10orf90 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV52961146; called by muse, mutect2, varscan2
- CARMIL2 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58026196, COSV58030422; called by muse, mutect2, varscan2
- CAT | c.1388T>C p.I463T | Missense Mutation (SNP) | VAF 88/111 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV53812583; called by muse, mutect2, varscan2
- CCDC51 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1436184786, COSV56488331; called by muse, mutect2, varscan2
- CCDC88A | c.3601C>T p.R1201C | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs762374538, COSV55058197; called by muse, mutect2, varscan2
- CD244 | c.1034T>C p.I345T (on ENST00000368033 / NM_001166663.2; = p.I340T on NM_016382.4) | Missense Mutation (SNP) | VAF 30/371 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs776700284, COSV54436612; called by muse, mutect2
- CLVS1 | c.646C>G p.R216G | Missense Mutation (SNP) | VAF 196/325 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57970289, COSV57980739; called by muse, mutect2, varscan2
- CNGB1 | c.2956A>T p.N986Y | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV51905096; called by muse, mutect2, varscan2
- CNNM2 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV63996322; called by muse, mutect2, varscan2
- COG7 | c.685A>G p.K229E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs140030187; called by muse, mutect2, varscan2
- CPSF3 | c.946C>T p.H316Y | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.095); catalogued as COSV53011198; called by muse, mutect2, varscan2
- CTNNA2 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777032066, COSV63569988, COSV63590877; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748013264, COSV54746199; called by muse, mutect2, varscan2
- CYTH3 | c.562+2T>G p.X188_splice | Splice Site (SNP) | VAF 32/114 reads (28%) | catalogued as COSV63440543; called by muse, mutect2, varscan2
- DCPS | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs754132367, COSV55010833; called by muse, mutect2, varscan2
- DPEP1 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.172); catalogued as COSV55361544, COSV99878568; called by muse, mutect2, varscan2
- DPP8 | c.681G>C p.W227C (on ENST00000341861 / NM_001320875.2; = p.W211C on NM_017743.6) | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV55679271, COSV55682004; called by muse, mutect2, varscan2
- DST | c.22031T>A p.L7344H (on ENST00000361203 / NM_001374722.1; = p.L5054H on NM_015548.5) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV55033079; called by muse, mutect2, varscan2
- EIF4EBP1 | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.053); catalogued as COSV58774943; called by muse, mutect2, varscan2
- EP300 | c.3284G>T p.S1095I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1270990992, COSV54341479; called by muse, mutect2, varscan2
- EPHA2 | c.149A>G p.K50R | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs781061644, COSV64454323; called by muse, mutect2, varscan2
- ESPL1 | c.3112G>A p.E1038K | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57761940; called by muse, mutect2, varscan2
- EXOG | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV55064337, COSV99815407; called by muse, mutect2, varscan2
- FAAP20 | c.131T>A p.L44Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV66032230; called by muse, mutect2, varscan2
- FBN1 | c.2425G>A p.D809N | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57326662; called by muse, mutect2, varscan2
- GAD1 | c.648T>A p.Y216* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as rs756971067; called by muse, mutect2
- GP5 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs747024152; called by muse, varscan2
- H3C1 | c.236T>G p.F79C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV55120299; called by muse, mutect2, varscan2
- HERC2 | c.5466C>T p.G1822= | Splice Region (SNP) | VAF 16/46 reads (35%) | catalogued as COSV55342672; called by muse, mutect2, varscan2
- HIVEP2 | c.3154G>C p.D1052H | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50039393, COSV99056224; called by muse, mutect2, varscan2
- HNRNPAB | c.928+1G>A p.X310_splice | Splice Site (SNP) | VAF 13/21 reads (62%) | catalogued as COSV57425698; called by muse, mutect2
- HPD | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV56643180; called by muse, mutect2, varscan2
- HRNR | c.6413C>T p.S2138F | Missense Mutation (SNP) | VAF 69/1841 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1396688561; called by muse, mutect2
- HSD17B4 | c.1900T>C p.S634P (on ENST00000414835 / NM_001199291.3; = p.S609P on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.662); catalogued as COSV56338292; called by muse, mutect2, varscan2
- IBTK | c.2857G>A p.V953I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV60395243; called by muse, mutect2, varscan2
- ICA1 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.625); catalogued as COSV55582563; called by muse, mutect2
- IFIH1 | c.1576G>T p.D526Y | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs758807886, COSV55129124; called by muse, mutect2, varscan2
- IGIP | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV60964569; called by muse, mutect2, varscan2
- IMPA2 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 61/79 reads (77%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV52320691; called by muse, mutect2, varscan2
- INSL4 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs188521238, COSV53329748; called by muse, mutect2, varscan2
- INTS1 | c.2324A>G p.Y775C | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV67179121; called by muse, mutect2, varscan2
- ITIH3 | c.1331A>G p.H444R | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs971879359, COSV69649869; called by muse, mutect2, varscan2
- KCNA2 | c.1204A>T p.I402F | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV60371098; called by muse, mutect2, varscan2
- KCNH8 | c.3142A>C p.S1048R | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs772616108, COSV60472778; called by muse, mutect2, varscan2
- KCTD16 | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs1220306308, COSV72580212; called by muse, mutect2, varscan2
- LARP4 | c.408G>T p.L136F | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53325855; called by muse, mutect2, varscan2
- LASP1 | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58805598, COSV58805634; called by muse, mutect2, varscan2
- LMF1 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs772059919, COSV51895872; called by muse, mutect2, varscan2
- LPAR3 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 130/244 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV65454599; called by muse, mutect2, varscan2
- LRP2 | c.7479G>C p.M2493I | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55567887; called by muse, mutect2, varscan2
- LRRC17 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as COSV50867081; called by muse, mutect2, varscan2
- MAF1 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100075265, COSV59364089; called by muse, mutect2, varscan2
- MAP3K1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs778331321, COSV68126228, COSV68127676, COSV68128538; called by muse, mutect2
- MAP4K3 | c.2174T>C p.F725S | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55716724; called by muse, mutect2, varscan2
- MORF4L1 | c.946A>T p.T316S (on ENST00000331268 / NM_206839.2; = p.T277S on NM_006791.4) | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.301); catalogued as COSV58705311; called by muse, mutect2, varscan2
- MRGBP | c.232T>G p.W78G | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV65111669; called by muse, mutect2, varscan2
- MRGPRX1 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs1050560364, COSV57109029; called by muse, mutect2, varscan2
- MRPS22 | c.265A>T p.T89S (on ENST00000310776 / NM_001363893.1; = p.T90S on NM_020191.4) | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV60350922; called by muse, mutect2, varscan2
- MSL3 | c.1171A>G p.K391E (on ENST00000312196 / NM_078629.4; = p.K225E on NM_006800.4) | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.306); catalogued as COSV56495257; called by muse, mutect2, varscan2
- MST1R | c.3339C>G p.I1113M | Missense Mutation (SNP) | VAF 95/183 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV56572362; called by muse, mutect2, varscan2
- MYH10 | c.5633G>C p.R1878P | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52607914; called by muse, mutect2, varscan2
- MYH9 | c.2629C>T p.Q877* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV99340092; called by muse, mutect2, varscan2
- MYO15A | c.4266G>C p.Q1422H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs1241558718, COSV52762685; called by muse, mutect2, varscan2
- MYO9A | c.3116T>C p.F1039S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs758650377, COSV61855589; called by muse, mutect2, varscan2
- MYOM3 | c.3528T>G p.I1176M | Missense Mutation (SNP) | VAF 258/323 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58399024; called by muse, mutect2, varscan2
- NCAPD2 | c.832A>G p.I278V | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.178); catalogued as COSV59701706; called by muse, mutect2, varscan2
- NDNF | c.968T>G p.M323R | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV65634440; called by muse, mutect2, varscan2
- NIPBL | c.1317G>C p.Q439H | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.261); catalogued as COSV56954616, COSV56961450; called by muse, mutect2, varscan2
- NKTR | c.4334G>A p.S1445N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV51774279; called by muse, mutect2, varscan2
- NLRC4 | c.1223T>A p.F408Y | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV61594205; called by muse, mutect2, varscan2
- NPC1L1 | c.3239A>G p.H1080R | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV56928905; called by muse, mutect2, varscan2
- NPY5R | c.199A>G p.M67V | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV58453325; called by muse, mutect2, varscan2
- NR2C2 | c.523A>G p.K175E (on ENST00000393102; = p.K194E on NM_003298.5) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV60148219; called by muse, mutect2, varscan2
- NSD1 | c.5719A>G p.I1907V | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV61781888; called by muse, mutect2, varscan2
- NT5C1B | c.1091C>T p.A364V (on ENST00000359846 / NM_001199086.2; = p.A304V on NM_033253.4) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV58398166; called by muse, mutect2, varscan2
- NUAK1 | c.291G>T p.M97I | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV54606876; called by muse, mutect2, varscan2
- OGT | c.2456C>T p.T819I | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV65482166; called by muse, mutect2, varscan2
- OR8H2 | c.398C>A p.T133K | Missense Mutation (SNP) | VAF 149/230 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100542285, COSV57946857; called by muse, mutect2, varscan2
- OTOP3 | c.914T>C p.M305T | Missense Mutation (SNP) | VAF 100/317 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60914484; called by muse, mutect2, varscan2
- PADI1 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763031946, COSV64938477, COSV64939053; called by muse, mutect2, varscan2
- PAF1 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV55395709; called by muse, mutect2, varscan2
- PCDH9 | c.158A>G p.N53S | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT tolerated (0.52); PolyPhen benign (0.101); catalogued as rs1490237351, COSV60578509; called by muse, mutect2, varscan2
- PCDHA4 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as rs782583105, COSV63544869; called by muse, mutect2, varscan2
- PDE5A | c.1111A>G p.I371V | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs201004401, COSV53351472; called by muse, mutect2, varscan2
- PHF24 | c.787A>G p.I263V | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1202240809, COSV54276177; called by muse, mutect2, varscan2
- PHIP | c.4700G>C p.S1567T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV51508486; called by muse, mutect2, varscan2
- PHOX2B | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1442934701, COSV56930288; called by muse, varscan2
- PIGR | c.1130A>G p.E377G | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV62904769; called by muse, mutect2, varscan2
- PIH1D1 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 114/166 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs17844886, COSV51808267; called by muse, mutect2, varscan2
- PIK3C2A | c.4423A>G p.I1475V | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs747902809, COSV56402791, COSV56405688; called by muse, mutect2, varscan2
- PML | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as COSV51451990; called by muse, mutect2, varscan2
- POLR3H | c.359+1G>T p.X120_splice | Splice Site (SNP) | VAF 28/60 reads (47%) | catalogued as COSV53444651; called by muse, mutect2, varscan2
- POTEH | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 124/990 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58885630; called by muse, varscan2
- PPP1R3D | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.543); catalogued as rs374884643; called by muse, mutect2, varscan2
- PPP1R9A | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56905139, COSV56905707; called by muse, mutect2, varscan2
- PRDM1 | c.521C>A p.A174D | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100958955, COSV64846374; called by muse, mutect2, varscan2
- PRR35 | c.89C>G p.P30R | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53464758, COSV53465414; called by muse, mutect2, varscan2
- PSMB8 | c.808C>T p.Q270* (on ENST00000374882 / NM_148919.4; = p.Q266* on NM_004159.5) | Nonsense Mutation (SNP) | VAF 56/108 reads (52%) | catalogued as rs752931080; called by muse, mutect2, varscan2
- PTP4A2 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV59775160; called by muse, mutect2, varscan2
- REC8 | c.1436T>G p.L479R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1201760222, COSV61017884; called by muse, mutect2, varscan2
- RECQL | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 108/166 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.363); catalogued as COSV53711220; called by muse, mutect2, varscan2
- RFWD3 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV63097798; called by muse, mutect2, varscan2
- RIMBP2 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761925052, COSV55480709; called by muse, mutect2, varscan2
- RP1 | c.5079G>T p.L1693F | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs751088395, COSV55123753; called by muse, mutect2, varscan2
- SDHAF3 | c.260A>G p.E87G | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV64491877; called by muse, mutect2, varscan2
- SDK1 | c.4130-2A>T p.X1377_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as COSV67383498; called by muse, mutect2, varscan2
- SH2B1 | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV59465614; called by muse, mutect2, varscan2
- SLC25A36 | c.795del p.Q266Rfs*19 (on ENST00000324194 / NM_001104647.3; = p.Q265Rfs*19 on NM_018155.3) | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | catalogued as rs1559818665; called by mutect2, pindel, varscan2
- SLC44A4 | c.2096A>T p.N699I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV57668694; called by muse, mutect2, varscan2
- SLC4A1 | c.362T>C p.L121P | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52262322; called by muse, mutect2, varscan2
- SLF2 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 96/136 reads (71%) | SIFT tolerated (0.25); PolyPhen benign (0.085); catalogued as COSV53277996; called by muse, mutect2, varscan2
- SMARCA2 | c.2683C>G p.L895V | Missense Mutation (SNP) | VAF 78/90 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61810978; called by muse, mutect2, varscan2
- SPAM1 | c.1190A>G p.Y397C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159486666, COSV56146608; called by muse, mutect2, varscan2
- SULF1 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 76/132 reads (58%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.976); catalogued as COSV52687878, COSV52689733; called by muse, mutect2, varscan2
- SYTL3 | c.1343A>C p.N448T (on ENST00000611299 / NM_001242394.1; = p.N380T on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV51913774; called by muse, mutect2, varscan2
- SZT2 | c.1567C>A p.P523T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65173011; called by muse, mutect2, varscan2
- TAF7L | c.916A>T p.M306L | Missense Mutation (SNP) | VAF 75/122 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV61257779; called by muse, mutect2, varscan2
- TBX5 | c.425C>G p.P142R | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100091862; called by mutect2, varscan2
- TECPR1 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV65784698; called by muse, mutect2, varscan2
- TENM4 | c.3718G>A p.D1240N | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53657529; called by muse, mutect2, varscan2
- TMOD1 | c.547G>C p.V183L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV52251421, COSV52251519; called by muse, mutect2, varscan2
- TMPO | c.553G>C p.D185H | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54124690; called by muse, mutect2, varscan2
- TNMD | c.809G>C p.R270P | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as COSV65977612; called by muse, mutect2, varscan2
- TNPO1 | c.29A>C p.E10A | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV61523392; called by muse, mutect2, varscan2
- TNRC6C | c.3439C>T p.H1147Y | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56947768; called by muse, mutect2, varscan2
- TPK1 | c.354+1G>A p.X118_splice | Splice Site (SNP) | VAF 62/128 reads (48%) | catalogued as rs779798917, COSV63645746; called by muse, mutect2, varscan2
- TRHDE | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 86/545 reads (16%) | catalogued as COSV53839468; called by muse, varscan2
- TRHDE | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 130/680 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as COSV53859489; called by muse, varscan2
- TRIM25 | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.124); catalogued as rs1266754348, COSV57545232; called by muse, mutect2, varscan2
- TRIM9 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.142); catalogued as rs966445839, COSV53622923; called by muse, mutect2, varscan2
- TRIO | c.7764G>A p.M2588I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs368253813; called by muse, mutect2
- TRPC1 | c.769G>A p.D257N (on ENST00000476941 / NM_001251845.2; = p.D223N on NM_003304.4) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56428780; called by muse, mutect2, varscan2
- TSTD2 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.224); catalogued as rs754264795, COSV52251429; called by muse, mutect2, varscan2
- UBE4B | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); catalogued as COSV53533900; called by muse, mutect2, varscan2
- UGT1A1 | c.286G>C p.G96R | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as COSV59383541, COSV59395627; called by muse, varscan2
- UGT1A1 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 97/185 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV100530344, COSV59395637; called by muse, varscan2
- USP19 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.962); catalogued as rs772803938, COSV59732348; called by muse, mutect2, varscan2
- VANGL2 | c.447C>A p.F149L | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.14); catalogued as COSV63605157; called by muse, mutect2
- VKORC1 | c.406A>G p.I136V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs781537497, COSV54926021; called by muse, mutect2, varscan2
- VPS13B | c.1238A>G p.Y413C | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62023979; called by muse, mutect2, varscan2
- WDR36 | c.2513A>T p.N838I | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.337); catalogued as COSV72605411; called by muse, mutect2, varscan2
- WDR6 | c.2614C>T p.Q872* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV58244251; called by muse, mutect2, varscan2
- WNT5A | c.1093G>C p.V365L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52838877; called by muse, mutect2, varscan2
- WWP2 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 272/517 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs891887656, COSV63125157; called by muse, mutect2, varscan2
- ZFC3H1 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT tolerated, low confidence (0.7); PolyPhen possibly damaging (0.502); catalogued as COSV57349691; called by muse, mutect2
- ZFHX4 | c.4079G>T p.W1360L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51486085, COSV51490846; called by muse, mutect2, varscan2
- ZFYVE9 | c.1214C>G p.T405S | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV55098035; called by muse, mutect2, varscan2
- ZNF217 | c.3020C>T p.S1007F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.271); catalogued as rs780214486, COSV56600887; called by muse, mutect2, varscan2
- ZNF23 | c.158A>T p.N53I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV61841530; called by muse, mutect2, varscan2
- ZNF710 | c.965C>A p.P322Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51564969; called by muse, mutect2, varscan2
- ZNF829 | c.580A>C p.S194R | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV66986778; called by muse, mutect2, varscan2
- ADGRG4 | c.2276T>G p.L759* | Nonsense Mutation (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- ANKRD11 | c.7264A>G p.I2422V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- AP3B2 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AVIL | c.1818-5_1832del p.X606_splice | Splice Site (DEL) | VAF 45/93 reads (48%) | called by mutect2, pindel, varscan2
- B3GALT4 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- CDK13 | c.1779_1792del p.K594Tfs*20 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | called by mutect2, pindel
- CDK5RAP2 | c.1877A>G p.Y626C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.135); called by muse, mutect2
- EIF3A | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 34/139 reads (24%) | called by muse, mutect2, varscan2
- ELL2 | c.606_656del p.Q203_Y219del | In Frame Del (DEL) | VAF 62/187 reads (33%) | called by mutect2, pindel
- FLOT1 | c.836_860del p.L279Rfs*11 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | called by mutect2, pindel
- HIPK2 | c.1901G>A p.S634N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- HK3 | c.2524dup p.A842Gfs*89 | Frame Shift Ins (INS) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- LSS | c.429-14_429-3del | Splice Region (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- MED9 | c.406A>T p.K136* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- MGMT | c.529C>G p.H177D (on ENST00000306010; = p.H146D on NM_002412.5) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYRF | c.1644_1662del p.Q549Sfs*50 (on ENST00000278836 / NM_001127392.3; = p.Q540Sfs*50 on NM_013279.4) | Frame Shift Del (DEL) | VAF 12/21 reads (57%) | called by mutect2, pindel, varscan2
- NBN | c.2071-13_2077del p.X691_splice | Splice Site (DEL) | VAF 61/147 reads (41%) | called by mutect2, pindel, varscan2
- NFAT5 | c.2113_2127del p.L705_T709del | In Frame Del (DEL) | VAF 17/74 reads (23%) | called by mutect2, pindel, varscan2
- NUP107 | c.1594_1606del p.S532Pfs*15 | Frame Shift Del (DEL) | VAF 31/311 reads (10%) | called by mutect2, pindel
- PKD1L2 | c.1186_1198del p.E396Kfs*9 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | called by mutect2, pindel, varscan2
- RYR2 | c.14305_14308del p.L4769Pfs*5 | Frame Shift Del (DEL) | VAF 54/328 reads (16%) | called by pindel, varscan2
- SETD2 | c.5971G>T p.E1991* | Nonsense Mutation (SNP) | VAF 77/160 reads (48%) | called by muse, mutect2, varscan2
- SGK1 | c.575_589del p.R192_E196del | In Frame Del (DEL) | VAF 20/41 reads (49%) | called by mutect2, pindel, varscan2
- ZNF768 | c.43_52del p.V15Lfs*4 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- ZSCAN5A | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- ADRM1 | c.903C>T p.L301= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs758137004; called by muse, mutect2, varscan2
- AL645922.1 | c.3627G>A p.K1209= | Silent (SNP) | VAF 69/249 reads (28%) | catalogued as COSV64888366; called by muse, mutect2, varscan2
- ASXL3 | c.1569A>G p.S523= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV52475341; called by muse, mutect2, varscan2
- ATP2B4 | c.381A>G p.E127= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV58182219; called by muse, mutect2, varscan2
- BRD2 | c.1672C>A p.R558= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV66374278, COSV66374670; called by muse, mutect2, varscan2
- CFAP45 | c.1479G>C p.R493= | Silent (SNP) | VAF 59/264 reads (22%) | catalogued as COSV63650391; called by muse, mutect2, varscan2
- CRYZL1 | c.150G>A p.L50= | Silent (SNP) | VAF 54/148 reads (36%) | catalogued as COSV51678972; called by muse, mutect2, varscan2
- CSF3R | c.147G>A p.K49= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV58970209; called by muse, mutect2, varscan2
- CTSG | c.273G>A p.A91= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as rs533433194, COSV53536485; called by muse, mutect2, varscan2
- CUX2 | c.2280G>T p.P760= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs746460540, COSV55643484; called by muse, mutect2, varscan2
- DPYSL4 | c.1674C>T p.I558= | Silent (SNP) | VAF 34/196 reads (17%) | catalogued as COSV53841806, COSV53844380; called by muse, varscan2
- DRD5 | c.1248C>T p.N416= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs768995915, COSV58576675; called by muse, mutect2, varscan2
- FBN1 | c.5283C>G p.T1761= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs373887214, COSV57326652; called by muse, mutect2, varscan2
- GRIK5 | c.486C>T p.S162= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV53483728; called by muse, mutect2, varscan2
- IL20RA | c.828T>C p.Y276= | Silent (SNP) | VAF 139/218 reads (64%) | catalogued as rs551010767, COSV57359786; called by muse, varscan2
- KIDINS220 | c.2316C>T p.I772= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV56757617; called by muse, mutect2, varscan2
- KNDC1 | c.1977C>T p.C659= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs773900126; called by muse, mutect2, varscan2
- LMO7 | c.798A>G p.E266= (on ENST00000357063; = p.E281= on NM_005358.5) | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV58544434; called by muse, mutect2, varscan2
- LPL | c.1290G>A p.K430= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV60932419; called by muse, mutect2, varscan2
- LRGUK | c.1734G>A p.E578= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as rs1354665963, COSV53641973; called by muse, mutect2, varscan2
- MATR3 | c.1356T>C p.D452= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV63079052; called by muse, mutect2, varscan2
- MDFI | c.582G>C p.S194= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV57822670; called by muse, mutect2, varscan2
- MMP20 | c.87C>G p.A29= | Silent (SNP) | VAF 52/74 reads (70%) | catalogued as COSV52777486; called by muse, mutect2, varscan2
- MOV10L1 | c.1573C>T p.L525= | Silent (SNP) | VAF 40/52 reads (77%) | catalogued as COSV53176315; called by muse, mutect2, varscan2
- NMU | c.369T>G p.V123= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV51701413; called by muse, mutect2, varscan2
- OR56B4 | c.396C>T p.I132= | Silent (SNP) | VAF 74/101 reads (73%) | catalogued as COSV57205265; called by muse, mutect2, varscan2
- OR6C70 | c.828T>C p.N276= | Silent (SNP) | VAF 18/206 reads (9%) | catalogued as COSV59245256; called by muse, mutect2
- P2RY13 | c.288T>C p.L96= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV56391823; called by muse, mutect2, varscan2
- PCDH10 | c.267C>A p.P89= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV52101109; called by muse, mutect2, varscan2
- PLEKHG3 | c.417G>T p.T139= (on ENST00000394691; = p.T195= on NM_001308147.2) | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs144144480, COSV55982656; called by muse, varscan2
- PLK1 | c.1575C>T p.L525= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV55623878; called by muse, mutect2, varscan2
- PMM1 | c.261C>T p.H87= | Silent (SNP) | VAF 54/95 reads (57%) | catalogued as rs766611904, COSV53448738; called by muse, mutect2, varscan2
- RAD51C | c.492T>C p.F164= | Silent (SNP) | VAF 98/182 reads (54%) | catalogued as COSV53623857; called by muse, mutect2, varscan2
- SCAPER | c.2491C>T p.L831= | Silent (SNP) | VAF 37/61 reads (61%) | catalogued as COSV57749502; called by muse, mutect2, varscan2
- SEMA6A | c.237T>A p.V79= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV57315793; called by muse, mutect2
- SPTAN1 | c.111T>C p.R37= | Silent (SNP) | VAF 78/136 reads (57%) | catalogued as COSV63989159; called by muse, mutect2, varscan2
- STAG1 | c.354G>A p.L118= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV52620027; called by muse, mutect2, varscan2
- SYNPO2L | c.2688G>A p.Q896= (on ENST00000394810 / NM_001114133.3; = p.Q672= on NM_024875.5) | Silent (SNP) | VAF 34/49 reads (69%) | catalogued as COSV65736515; called by muse, mutect2, varscan2
- TFDP2 | c.1194C>G p.A398= (on ENST00000489671 / NM_001178139.2; = p.A338= on NM_006286.5) | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as COSV57710280; called by muse, mutect2, varscan2
- UBR4 | c.9786C>G p.S3262= | Silent (SNP) | VAF 23/167 reads (14%) | catalogued as COSV100921252, COSV64396347; called by muse, mutect2, varscan2
- VSIG4 | c.1131C>T p.Y377= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs200220547, COSV66074567; called by muse, mutect2, varscan2
- WDR88 | c.1185T>C p.I395= | Silent (SNP) | VAF 84/121 reads (69%) | catalogued as COSV63452325; called by muse, mutect2, varscan2
- ZNF292 | c.6993C>G p.P2331= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV100370624, COSV60544679; called by muse, mutect2, varscan2
- ZNF521 | c.1449C>T p.S483= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as rs201698806; called by muse, mutect2, varscan2
- ZNFX1 | c.93T>C p.A31= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV65578079; called by muse, mutect2, varscan2
- C6orf223 | n.735C>T | RNA (SNP) | VAF 8/20 reads (40%) | catalogued as rs763722935, COSV60735936; called by muse, mutect2
- CASR | c.1378-6224G>C | Intron (SNP) | VAF 65/169 reads (38%) | catalogued as COSV56140323; called by muse, mutect2, varscan2
- GRK5 | c.148+7181C>T | Intron (SNP) | VAF 25/75 reads (33%) | catalogued as rs771796945, COSV67312638; called by muse, mutect2, varscan2
- RBM44 | c.-98-1881_-98-1873del | Intron (DEL) | VAF 24/84 reads (29%) | called by mutect2, pindel, varscan2
- RUNX2 | c.-34G>T | 5'UTR (SNP) | VAF 19/44 reads (43%) | catalogued as COSV60947183; called by muse, mutect2, varscan2
- SEPTIN9 | c.722-6400C>T | Intron (SNP) | VAF 9/39 reads (23%) | catalogued as rs755337865, COSV61209316; called by muse, mutect2, varscan2
- TMEM107 | c.*620C>T | 3'UTR (SNP) | VAF 9/30 reads (30%) | catalogued as rs374740618; called by muse, mutect2, varscan2
